Somatic mutation profile of tumor specimen 0DSJY5 from CCDI case PBCIAM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.0 years (2,179 days).
Specimen 0DSJY5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4cd8cef-72c3-492b-b627-c4548a90ecc5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSJYI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5cd7af36-41af-4284-8b12-37ecde9fb58e

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXO28 | c.554A>G p.N185S | Missense Mutation (SNP) | VAF 23/313 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs199672778; called by muse, mutect2
- HMCN2 | c.13549G>A p.E4517K | Missense Mutation (SNP) | VAF 125/285 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs1052679196; called by muse, mutect2, varscan2
- MTRNR2L10 | c.32T>A p.L11H | Missense Mutation (SNP) | VAF 26/285 reads (9%) | PolyPhen probably damaging (0.941); called by muse, mutect2
